Surgical pathology report (de-identified scan), TCGA case TCGA-FF-8042, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-8042-01A (Primary Tumor).

ADDENDUM**ADDENDUM TO HISTOPATHOLOGY REPORT** [REDACTED]

The following immunoprofile is obtained in this malignant lymphoma:

CD3, 5, 10: Negative
Cyclin D1: Negative
CD 21, 23: Negative. There is a suggestion of an adjacent follicular area with CD 21, but no staining with CD 10.

BCL2, 6: Positive for both. Though BCL 6 positive, cells are CD 10 negative
CD 20: Positive
CD 79a: Positive
Ki 67/MIB1: Activity from 80 to 90%.

In summary, this tumor is classified as a Diffuse large "B" cell lymphoma (CD20 and CD79A+, CD 5, 10 and cyclin D1-). This lymphoma has a diffuse pattern, with tumor cells of medium to large size and clearly marking with CD 20 and CD 79a and negative for Cyclin D1.

Amended Diagnosis:
Diffuse, large "B" cell lymphoma (DLBCL).

NOTE : Please see below for original report.

Pathologist : [REDACTED]

DIAGNOSIS

Supraclavicular lymph node, biopsy:
- Malignant lymphoma, immunoprofile and classification will follow with addendum.

GROSS DESCRIPTION

Received in formalin is a specimen labelled with patient's data, and designated "left supraclavicular lymph node". It consists of two irregular pieces of fleshy tissue measuring 1.5 x 1 x 0.3cm and 1.1 x 1 x 0.5cm. (A1; no reserve)

MICROSCOPIC DESCRIPTION

This is an adequate excisional biopsy. The features are in keeping with a malignant lymphoma. Immunoprofile ordered and addendum report will follow with typing of malignant lymphoma. There are areas of geographic necrosis, suggestive of changes post fine needle biopsy.

Pathologist : [REDACTED]

Source: NCI Genomic Data Commons file 3f8c2629-4b08-48b7-b7d7-641eef456949 (TCGA-FF-8042.6CDCAAC9-0654-4BDA-8344-CE0B810ABB15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).